Somatic mutation profile of tumor specimen 0DGQC3 from CCDI case PBBTRC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (551 days).
Specimen 0DGQC3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7f747a6-84c2-4f20-921d-95e955532fd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGQAF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a721f561-be60-4d19-a9ee-3a6d1c685828

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4X1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 223/1152 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778621423, COSV64150522; called by muse, mutect2, varscan2
- MMP8 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 168/820 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as COSV99368980; called by muse, varscan2
- ZNF316 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 21/543 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs926973150; called by muse, mutect2
- BAZ2B | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 38/1488 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 23/726 reads (3%) | called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 30/1018 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- NR5A2 | c.80A>G p.D27G | Missense Mutation (SNP) | VAF 181/1060 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 34/1000 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
